Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AAB9, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AAB9-01A (Primary Tumor).

[page 1 of 5]
ICD O-3

Surgery date: Surgical Pathology
REVISED REPORT (Revised information underlined)

Adenocarcinoma, duct NOS
8500/3

Site: Pancreas head
C25.0

9/5/14

DIAGNOSIS:

D. Pancreas, head, duodenum, gallbladder, and common bile duct, portion jejunum, pyloro-sparing Whipple resection: Invasive grade 3 (of 4) ductal adenocarcinoma is identified forming a solid 4.0 x 3.0 x 3.0 cm mass causing a stricture of the distal common bile duct.

The tumor extends beyond the pancreas to involve the peripancreatic soft tissue. It infiltrates into the muscularis propria of the duodenal wall and the adventitia of superior mesenteric vein (a 4.0 cm segment of superior mesenteric/portal vein resected on block is present). Perineural invasion is present. Tumor necrosis is absent. All surgical resection margins are negative for tumor (minimum tumor free margin, less than 0.1 cm, anterior soft tissue margin). Multiple (5 of 34) regional lymph nodes are positive for metastatic adenocarcinoma. The gallbladder is unremarkable.

A. Lymph nodes, hepatic artery, biopsy: Multiple (2) lymph nodes are negative for tumor.

B. Pancreas, neck margin, excision: Positive for tumor. A lymph node is also metastatically involved.

C. Pancreas, body margin, excision: A microfocus of carcinoma is present.

E. Vein, superior mesenteric, margin, excision: Negative for tumor.

F. Vein, portal margin, excision: Negative for tumor.

G. Hepatic duct, margin, excision: Invasive adenocarcinoma is present in the soft tissues surrounding hepatic duct nearly circumferentially.

H. Hepatic duct, new common margin, excision: Negative for tumor.

With available surgical material, [AJCC pT3N1] (7th edition, 2010).

Frozen section histologic interpretation of hepatic artery lymph nodes, neck of pancreas margin, and body of pancreas margin, performed by:

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes

[page 2 of 5]
identified on permanent section review will be reflected in a revised report.

Interpreted by:

Report electronically signed by:

Transcribed by:

AMENDMENTS: (Previous Signout Date:

Revision Description: Part C: On permanent section, a microscopic focus of invasive carcinoma is identified involving the pancreas body margin. On review of frozen section slides, two small malignant glands are identified, originally misinterpreted as reactive.

....Original Diagnosis....

D. Pancreas, head, duodenum, gallbladder, and common bile duct, portion jejunum, pyloro-sparing Whipple resection: Invasive grade 3 (of 4) ductal adenocarcinoma is identified forming a solid 4.0 x 3.0 x 3.0 cm mass causing a stricture of the distal common bile duct. The tumor extends beyond the pancreas to involve the peripancreatic soft tissue. It infiltrates into the muscularis propria of the duodenal wall and the adventitia of superior mesenteric vein (a 4.0 cm segment of superior mesenteric/portal vein resected on block is present). Perineural invasion is present. Tumor necrosis is absent. All surgical resection margins are negative for tumor (minimum tumor free margin, less than 0.1 cm, anterior soft tissue margin). Multiple (5 of 34) regional lymph nodes are positive for metastatic adenocarcinoma. The gallbladder is unremarkable.

A. Lymph nodes, hepatic artery, biopsy: Multiple (2) lymph nodes are negative for tumor.

B. Pancreas, neck margin, excision: Positive for tumor. A lymph node is also metastatically involved.

C. Pancreas, body margin, excision: Margin is negative for tumor. Invasive carcinoma is present 0.2 cm away from the resection margin.

E. Vein, superior mesenteric, margin, excision: Negative for tumor.

F. Vein, portal margin, excision: Negative for tumor.

G. Hepatic duct, margin, excision: Invasive adenocarcinoma is present in the soft tissues surrounding hepatic duct nearly circumferentially.

H. Hepatic duct, new common margin, excision: Negative for tumor.

[page 3 of 5]
With available surgical material, [AJCC pT3N1] (7th edition, 2010).

Frozen section histologic interpretation of hepatic artery lymph nodes, neck of pancreas margin, and body of pancreas margin, performed by:

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Signing Pathologist

GROSS DESCRIPTION:

A. Received fresh labeled "hepatic artery lymph nodes" is a 1.1 x 1.0 x 0.4 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by

B. Received fresh labeled "neck of pancreas margin" is a 3.2 x 2.1 x 0.5 cm portion of pancreatic tissue with orientation. All submitted. Grossed by

C. Received fresh labeled "body of pancreas margin" is a 3.8 x 2.6 x 1.0 cm portion of pancreas with orientation. Representative sections are submitted. Grossed by

D. Received fresh labeled "head pancreas, gallbladder, duodenum, common bile duct, portion jejunum" is a Whipple specimen consisting of 27.0 cm in length of portion of duodenum, 6.0 x 4.0 x 4.0 cm portion of pancreas, a 4.0 cm segment of superior mesenteric vein/portal vein, and a 12.0 x 4.0 x 4.0 cm gallbladder. The pancreatic uncinate margin is inked yellow and shaved, the portal vein groove is inked black and submitted perpendicularly. There is a 4.0 x 3.0 x 3.0 cm diffusely infiltrative mass within the pancreatic head, 0.9 cm from the neck margin. The mass extends to portal vein and duodenum. The gallbladder contains no choleliths. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Grossed by

E. Received fresh labeled "SMV margin" is a 1.0 x 1.0 x 0.4 cm portion of blood vessel with orientation. All submitted. Grossed by

[page 4 of 5]
F. Received fresh labeled "portal vein margin" is a 1.0 x 1.0 x 0.2 cm portion of blood vessel with orientation. All submitted.
Grossed by

G. Received fresh labeled "hepatic duct margin" is a 1.1 x 1.1 x 0.6 cm portion of hepatic duct with orientation. Margin submitted.
Grossed by

H. Received fresh labeled "new common hepatic duct margin" is a 0.6 x 0.5 x 0.3 cm portion of pink-tan tubular soft tissue with orientation. Margin submitted. Grossed by

BLOCK SUMMARY:

Part A: Hepatic artery Lymph Nodes

- 1 Hepatic artery LN 2 (A1)

Part B: Neck of pancreas Margins

- 1 Neck of pancreas 1
- 2 Neck of pancreas 2
- 3 Neck of pancreas 3

Part C: Body of pancreas margin

- 1 Body of pancreas margin1
- 2 Body of pancreas margin2
- 3 Peripancreatic LN ? 1(C1)

Part D: Head pancreas, gallbladder, duodenum, common bile duct, portion jejunum

- 1 Uncinate margin 1
- 2 Uncinate margin 2-bottom
- 3 Uncinate margin 2-top
- 4 Periduodenal LNs 4(D1)
- 5 Periduodenal LNs 1(D2)
- 6 Periduodenal LNs 5(D3)
- 7 Periduodenal LNs 3(D4)
- 8 Peripancreatic LNs 3(D5)
- 9 Peripancreatic LNs 3(D6)
- 10 Ampulla
- 11 Common bile duct
- 12 Duodenum
- 13 Portal/sup mesenteric vein
- 14 Pancreatic head
- 15 Peripancreatic LNs 2(D7)
- 16 Peripancreatic LNs 2(D8)
- 17 Peripancreatic LNs 1(D9)
- 18 Peripancreatic LNs 3(D10)
- 19 Peripancreatic LNs 3(D11)
- 20 Peripancreatic LNs 3(D12)

[page 5 of 5]
- 21 Gallbladder
- 22 Peripancreatic LNs 2(D14)
- 23 Peripancreatic LNs 3(D15)
- 24 Peripancreatic LNs 3(D16)

Part E: SMV margin

- 1 Sup mesenteric vein margin

Part F: Portal vein margin

- 1 Portal vein margin

Part G: Hepatic duct Margins

- 1 Hepatic duct margin

Part H: New common hepatic duct Margins

- 1 New comm hepatic duct mg

Criteria	10/10/14	Yes	No

Source: NCI Genomic Data Commons file adbeb903-92f8-4766-846d-290541ee065a (TCGA-2J-AAB9.6E92E34F-4CB2-497C-8F3A-CF959CCF26CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).